Somatic mutation profile of tumor specimen TCGA-A7-A0CE-01A (aliquot TCGA-A7-A0CE-01A-11W-A019-09) from TCGA case TCGA-A7-A0CE, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 57.1 years (20,863 days).
Specimen TCGA-A7-A0CE-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) affeafc3-20c4-47df-8d28-063e04a07437.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A7-A0CE-10A (Blood Derived Normal), aliquot TCGA-A7-A0CE-10A-01W-A021-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/528628e5-34b8-41c7-a275-623b2bd05c2e

The open-access MAF lists 107 somatic variants for this specimen: 78 protein-altering or splice-affecting, 27 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 69, Silent 27, Nonsense Mutation 5, Intron 2, Frame Shift Ins 1, Splice Site 1, Frame Shift Del 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.463A>C p.T155P | Missense Mutation (SNP) | VAF 81/99 reads (82%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.794); catalogued as COSV52661985, COSV52698075, COSV52994812, COSV53498723; called by muse, mutect2, varscan2
- ABCA9 | c.2201T>C p.I734T | Missense Mutation (SNP) | VAF 24/100 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as COSV60623526; called by muse, mutect2, varscan2
- ANK1 | c.52A>T p.R18* | Nonsense Mutation (SNP) | VAF 92/453 reads (20%) | catalogued as COSV55879136; called by muse, mutect2, varscan2
- ANLN | c.461G>C p.R154P | Missense Mutation (SNP) | VAF 26/130 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV56075336; called by muse, mutect2, varscan2
- ATP6V1C1 | c.1016A>G p.Y339C | Missense Mutation (SNP) | VAF 63/142 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV67777851; called by muse, mutect2, varscan2
- BCHE | c.1753T>A p.W585R | Missense Mutation (SNP) | VAF 23/154 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52255768; called by muse, mutect2, varscan2
- CDC7 | c.1354G>C p.E452Q | Missense Mutation (SNP) | VAF 108/465 reads (23%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.984); catalogued as COSV52310283; called by muse, mutect2, varscan2
- CDK14 | c.1291G>A p.D431N (on ENST00000380050 / NM_001287135.2; = p.D413N on NM_012395.3) | Missense Mutation (SNP) | VAF 51/368 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as rs1229807116, COSV56031769; called by muse, mutect2, varscan2
- CEACAM5 | c.122C>G p.T41R | Missense Mutation (SNP) | VAF 105/449 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV55751765; called by muse, mutect2, varscan2
- COL28A1 | c.649C>T p.P217S | Missense Mutation (SNP) | VAF 58/328 reads (18%) | SIFT tolerated (0.73); PolyPhen benign (0.007); catalogued as COSV68081697; called by muse, mutect2, varscan2
- CORO1C | c.644C>T p.A215V | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.077); catalogued as COSV54595265; called by muse, mutect2, varscan2
- CXorf66 | c.313T>A p.C105S | Missense Mutation (SNP) | VAF 90/432 reads (21%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.553); catalogued as COSV65169142; called by muse, mutect2, varscan2
- CYP4F8 | c.445C>T p.R149C | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.55); catalogued as rs558107890, COSV57853829; called by muse, mutect2, varscan2
- CYSLTR1 | c.801T>G p.C267W | Missense Mutation (SNP) | VAF 45/142 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV64819927; called by muse, mutect2, varscan2
- DPPA3 | c.301T>A p.Y101N | Missense Mutation (SNP) | VAF 13/115 reads (11%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.766); catalogued as COSV61502919; called by muse, mutect2, varscan2
- DRAM1 | c.410C>G p.T137R | Missense Mutation (SNP) | VAF 52/191 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.703); catalogued as COSV51597388; called by muse, mutect2, varscan2
- DUSP7 | c.830T>G p.V277G | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56588937; called by muse, mutect2, varscan2
- DYSF | c.830T>G p.L277R | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV50296481; called by muse, mutect2, varscan2
- FAM117B | c.884A>G p.H295R | Missense Mutation (SNP) | VAF 39/142 reads (27%) | SIFT tolerated (0.15); PolyPhen benign (0.069); catalogued as COSV57418393; called by muse, mutect2, varscan2
- FAM171A1 | c.2242G>T p.E748* | Nonsense Mutation (SNP) | VAF 14/73 reads (19%) | catalogued as COSV65315429, COSV65316913; called by muse, mutect2, varscan2
- FAT1 | c.6226G>A p.D2076N | Missense Mutation (SNP) | VAF 56/331 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101499433; called by muse, mutect2, varscan2
- FCGBP | c.4348G>A p.E1450K | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.922); catalogued as rs782437809, COSV55434571; called by muse, mutect2, varscan2
- FYB1 | c.1568A>T p.K523I | Missense Mutation (SNP) | VAF 127/506 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs770878983, COSV60944794; called by muse, mutect2, varscan2
- GLG1 | c.1717C>G p.R573G | Missense Mutation (SNP) | VAF 83/170 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.452); catalogued as COSV52665981, COSV52675328; called by muse, mutect2, varscan2
- HECW1 | c.3746A>T p.K1249I | Missense Mutation (SNP) | VAF 49/191 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV67827083; called by muse, mutect2, varscan2
- HLF | c.727C>G p.R243G | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56829595, COSV56832137, COSV99872330; called by muse, mutect2, varscan2
- HYDIN | c.3498C>A p.N1166K | Missense Mutation (SNP) | VAF 23/197 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66831485; called by muse, mutect2, varscan2
- IMPDH2 | c.1283A>G p.N428S | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT tolerated (0.9); PolyPhen benign (0.001); catalogued as COSV58244715; called by muse, mutect2, varscan2
- IPP | c.607G>T p.A203S | Missense Mutation (SNP) | VAF 16/104 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.314); catalogued as COSV63432429; called by muse, mutect2, varscan2
- ISM2 | c.550A>T p.T184S | Missense Mutation (SNP) | VAF 42/84 reads (50%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV53634653; called by muse, mutect2, varscan2
- ITGAX | c.1155T>A p.N385K | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT tolerated (0.57); PolyPhen benign (0.012); catalogued as COSV51644718; called by muse, varscan2
- KDM5B | c.1654C>G p.L552V | Missense Mutation (SNP) | VAF 61/179 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52506905; called by muse, mutect2, varscan2
- KIF17 | c.3085C>G p.L1029V | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.681); catalogued as COSV56117580; called by muse, mutect2, varscan2
- LDB2 | c.559C>A p.L187M | Missense Mutation (SNP) | VAF 45/168 reads (27%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as COSV58766871; called by muse, mutect2, varscan2
- LHCGR | c.186A>C p.K62N | Missense Mutation (SNP) | VAF 50/244 reads (20%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.805); catalogued as COSV54295796; called by muse, mutect2, varscan2
- LILRA1 | c.1058A>T p.H353L | Missense Mutation (SNP) | VAF 30/90 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.216); catalogued as COSV52179915; called by muse, mutect2, varscan2
- MAEL | c.490C>T p.P164S | Missense Mutation (SNP) | VAF 14/186 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63304819; called by muse, mutect2
- MAEL | c.491C>T p.P164L | Missense Mutation (SNP) | VAF 14/190 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63304148; called by muse, mutect2
- MAPK4 | c.943T>A p.Y315N | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68541766; called by muse, mutect2, varscan2
- MTMR4 | c.1730G>A p.C577Y | Missense Mutation (SNP) | VAF 245/420 reads (58%) | SIFT deleterious (0.01); PolyPhen benign (0.374); catalogued as COSV60200233; called by muse, mutect2, varscan2
- MYCT1 | c.436C>T p.R146* | Nonsense Mutation (SNP) | VAF 77/363 reads (21%) | catalogued as rs751903305, COSV65891190; called by muse, mutect2, varscan2
- MYO7A | c.4075G>A p.E1359K | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.115); catalogued as rs753672693, COSV68684418; called by muse, mutect2
- NCEH1 | c.66C>G p.C22W | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.148); catalogued as COSV56434034; called by muse, mutect2, varscan2
- NPPA | c.58C>G p.L20V | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as COSV56739375; called by muse, mutect2
- OAZ3 | c.241G>A p.G81S | Missense Mutation (SNP) | VAF 12/160 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.137); catalogued as COSV100162571; called by muse, mutect2
- ONECUT2 | c.1435C>T p.R479C | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); catalogued as rs760843135, COSV72153068; called by muse, mutect2, varscan2
- OR5T1 | c.467T>A p.L156H | Missense Mutation (SNP) | VAF 175/527 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57302442; called by muse, mutect2, varscan2
- OR6K6 | c.32C>G p.S11C | Missense Mutation (SNP) | VAF 183/583 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.257); catalogued as COSV100933672, COSV63743943; called by muse, mutect2, varscan2
- PHLDB1 | c.1135C>T p.P379S | Missense Mutation (SNP) | VAF 45/64 reads (70%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV61877763; called by muse, mutect2, varscan2
- PIGG | c.762G>C p.E254D | Missense Mutation (SNP) | VAF 51/183 reads (28%) | SIFT tolerated (0.47); PolyPhen benign (0.058); catalogued as rs782615666, COSV56317525; called by muse, mutect2, varscan2
- PIK3C2G | c.2750T>A p.L917H (on ENST00000676171; = p.L876H on NM_004570.5) | Missense Mutation (SNP) | VAF 64/307 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56805714; called by muse, mutect2, varscan2
- PTPRZ1 | c.6479C>G p.S2160C | Missense Mutation (SNP) | VAF 74/416 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66434898; called by muse, varscan2
- QPCTL | c.351G>A p.K117= | Splice Region (SNP) | VAF 11/52 reads (21%) | catalogued as COSV50003673; called by muse, mutect2, varscan2
- RASL11B | c.481C>G p.Q161E | Missense Mutation (SNP) | VAF 38/84 reads (45%) | SIFT tolerated (0.19); PolyPhen benign (0.005); catalogued as COSV50534945; called by muse, mutect2, varscan2
- RFX1 | c.2143G>C p.A715P | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV54329143; called by muse, mutect2, varscan2
- RTL10 | c.877G>A p.E293K | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (0.69); PolyPhen benign (0.005); catalogued as COSV60735594; called by muse, mutect2
- SATL1 | c.1277T>A p.L426H (on ENST00000395409; = p.L613H on NM_001012980.2) | Missense Mutation (SNP) | VAF 101/156 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60576241; called by muse, mutect2, varscan2
- SLC26A3 | c.955G>T p.G319W | Missense Mutation (SNP) | VAF 88/229 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60639880; called by muse, mutect2, varscan2
- SMTNL1 | c.1124C>A p.A375D (on ENST00000399154; = p.A412D on NM_001105565.2) | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67699565; called by muse, mutect2, varscan2
- SON | c.7184A>G p.D2395G | Missense Mutation (SNP) | VAF 12/152 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.972); catalogued as COSV99278981; called by muse, mutect2
- SRRT | c.367A>T p.M123L | Missense Mutation (SNP) | VAF 36/84 reads (43%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as COSV61451916; called by muse, mutect2, varscan2
- STRN4 | c.535C>T p.R179* | Nonsense Mutation (SNP) | VAF 16/69 reads (23%) | catalogued as COSV54417845; called by muse, mutect2, varscan2
- SYNPO2 | c.532G>A p.V178M | Missense Mutation (SNP) | VAF 37/137 reads (27%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs778638880, COSV61109427; called by muse, mutect2, varscan2
- TBC1D25 | c.1645C>G p.P549A | Missense Mutation (SNP) | VAF 50/85 reads (59%) | SIFT tolerated (0.44); PolyPhen benign (0.045); catalogued as COSV65123541; called by muse, mutect2, varscan2
- TMIGD2 | c.308G>T p.S103I | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.637); catalogued as COSV56666685; called by muse, mutect2, varscan2
- TNC | c.5528G>A p.R1843H | Missense Mutation (SNP) | VAF 131/213 reads (62%) | SIFT tolerated (0.12); PolyPhen benign (0.103); catalogued as rs200602864, COSV60783649; called by muse, mutect2, varscan2
- TREH | c.396T>A p.H132Q | Missense Mutation (SNP) | VAF 14/20 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV50620664; called by muse, mutect2, varscan2
- TRERF1 | c.2354T>A p.L785* | Nonsense Mutation (SNP) | VAF 67/119 reads (56%) | catalogued as COSV61670176; called by muse, mutect2, varscan2
- TRIM46 | c.1543G>T p.G515C | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100584196, COSV58113063; called by muse, varscan2
- TTN | c.5108C>T p.P1703L (on ENST00000591111; = p.P1657L on NM_003319.4) | Missense Mutation (SNP) | VAF 38/121 reads (31%) | PolyPhen probably damaging (0.999); catalogued as COSV59994755; called by muse, mutect2, varscan2
- VCAN | c.9440A>C p.N3147T | Missense Mutation (SNP) | VAF 31/136 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54103161; called by muse, mutect2, varscan2
- ZFPL1 | c.244C>T p.R82C | Missense Mutation (SNP) | VAF 50/143 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs906433445, COSV51869161; called by muse, mutect2, varscan2
- ZZEF1 | c.5782A>G p.T1928A | Missense Mutation (SNP) | VAF 35/109 reads (32%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV67557082; called by muse, mutect2, varscan2
- EYA4 | c.74_83+28del p.X25_splice | Splice Site (DEL) | VAF 121/581 reads (21%) | called by mutect2, pindel
- NIPBL | c.4269dup p.V1424Cfs*6 | Frame Shift Ins (INS) | VAF 18/43 reads (42%) | called by mutect2, pindel, varscan2
- SALL1 | c.3333_3334delinsA p.P1112Lfs*92 | Frame Shift Del (DEL) | VAF 33/73 reads (45%) | called by pindel, varscan2*
- SARS1 | c.1459C>A p.Q487K | Missense Mutation (SNP) | VAF 14/139 reads (10%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.9); called by muse, mutect2
- TRAV40 | c.229G>C p.G77R | Missense Mutation (SNP) | VAF 77/223 reads (35%) | SIFT tolerated (0.6); PolyPhen benign (0.309); called by muse, mutect2, varscan2
- AGFG2 | c.882C>T p.S294= | Silent (SNP) | VAF 18/81 reads (22%) | catalogued as rs1214089425, COSV53544817, COSV53544996; called by muse, mutect2, varscan2
- CDC5L | c.249G>A p.R83= | Silent (SNP) | VAF 82/159 reads (52%) | catalogued as COSV65175816; called by muse, mutect2, varscan2
- CKMT1B | c.1095T>G p.G365= | Silent (SNP) | VAF 148/280 reads (53%) | catalogued as COSV100294609; called by muse, mutect2, varscan2
- DCC | c.3243A>T p.G1081= | Silent (SNP) | VAF 30/146 reads (21%) | catalogued as COSV71430918; called by muse, mutect2, varscan2
- FMO2 | c.1167G>C p.V389= | Silent (SNP) | VAF 31/181 reads (17%) | catalogued as COSV52947334; called by muse, mutect2, varscan2
- FOXM1 | c.2202C>T p.I734= | Silent (SNP) | VAF 4/81 reads (5%) | catalogued as COSV100700870; called by muse, mutect2
- FXR1 | c.1224C>T p.P408= | Silent (SNP) | VAF 50/202 reads (25%) | catalogued as rs759723969, COSV59762417; called by muse, mutect2, varscan2
- HCLS1 | c.408C>T p.V136= | Silent (SNP) | VAF 55/230 reads (24%) | catalogued as COSV58855748; called by muse, mutect2, varscan2
- HTR3E | c.747C>A p.L249= (on ENST00000415389 / NM_001256613.1; = p.L264= on NM_182589.2) | Silent (SNP) | VAF 69/282 reads (24%) | catalogued as COSV58946488; called by muse, mutect2, varscan2
- IGHMBP2 | c.609G>A p.A203= | Silent (SNP) | VAF 12/40 reads (30%) | catalogued as rs761677597, COSV54821710, COSV99661770; called by muse, mutect2, varscan2
- LRRIQ4 | c.1416G>A p.L472= | Silent (SNP) | VAF 8/248 reads (3%) | catalogued as COSV100540291; called by muse, mutect2
- MED12 | c.5607C>T p.P1869= | Silent (SNP) | VAF 20/58 reads (34%) | catalogued as COSV61337075; called by muse, mutect2, varscan2
- MGAT4A | c.468T>G p.L156= | Silent (SNP) | VAF 164/499 reads (33%) | catalogued as COSV53846658; called by muse, mutect2, varscan2
- MYH15 | c.3003C>A p.I1001= | Silent (SNP) | VAF 152/255 reads (60%) | catalogued as COSV56308201, COSV99843983; called by muse, mutect2, varscan2
- NARS2 | c.837G>C p.L279= | Silent (SNP) | VAF 38/188 reads (20%) | catalogued as COSV55251102; called by muse, mutect2, varscan2
- NOL6 | c.2688C>T p.P896= | Silent (SNP) | VAF 16/62 reads (26%) | catalogued as rs1187731031, COSV53040961; called by muse, mutect2, varscan2
- OR2G6 | c.918G>T p.L306= | Silent (SNP) | VAF 146/392 reads (37%) | catalogued as COSV58574152; called by muse, mutect2, varscan2
- OR2T3 | c.528T>A p.S176= | Silent (SNP) | VAF 287/688 reads (42%) | catalogued as COSV62082213; called by muse, mutect2, varscan2
- PLEKHG2 | c.1626C>T p.I542= | Silent (SNP) | VAF 6/58 reads (10%) | catalogued as rs1199823927, COSV99217703; called by muse, mutect2
- PRKAG2 | c.1122A>G p.V374= | Silent (SNP) | VAF 30/180 reads (17%) | catalogued as COSV55227378; called by muse, mutect2, varscan2
- RHOBTB2 | c.549C>T p.I183= | Silent (SNP) | VAF 4/60 reads (7%) | called by muse, mutect2
- SPATA16 | c.132A>T p.S44= | Silent (SNP) | VAF 193/859 reads (22%) | catalogued as COSV63528632; called by muse, mutect2, varscan2
- TRPV2 | c.1884C>A p.A628= | Silent (SNP) | VAF 15/80 reads (19%) | catalogued as COSV58427989; called by muse, mutect2, varscan2
- TSHZ3 | c.3192C>T p.H1064= | Silent (SNP) | VAF 39/95 reads (41%) | catalogued as rs201875959, COSV53669187; called by muse, mutect2, varscan2
- TUBD1 | c.1230T>G p.V410= | Silent (SNP) | VAF 12/234 reads (5%) | catalogued as COSV100360171; called by muse, mutect2
- UBC | c.477C>T p.T159= | Silent (SNP) | VAF 9/216 reads (4%) | catalogued as rs782066690; called by muse, mutect2
- VCAN | c.8820T>A p.V2940= | Silent (SNP) | VAF 11/258 reads (4%) | called by muse, mutect2
- CDC42BPA | c.4791+5090A>G | Intron (SNP) | VAF 20/71 reads (28%) | catalogued as rs886362734, COSV62009229; called by muse, mutect2, varscan2
- RXRG | c.49+7682_49+7683del | Intron (DEL) | VAF 10/87 reads (11%) | called by mutect2, pindel, varscan2
